Somatic mutation profile of tumor specimen TCGA-QF-A5YT-01A (aliquot TCGA-QF-A5YT-01A-11D-A31U-09) from TCGA case TCGA-QF-A5YT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Isthmus uteri; FIGO stage: Stage II; Tumor grade: G1; Age at diagnosis: 57.4 years (20,981 days).
Specimen TCGA-QF-A5YT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 843cc88f-44b4-43e0-a289-238562db20d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QF-A5YT-10A (Blood Derived Normal), aliquot TCGA-QF-A5YT-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46f9874b-1a35-4a4a-9297-5fe1584d440d

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP9A | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as rs1163348934, COSV100124378; called by muse, mutect2
- DMBT1 | c.820C>A p.Q274K | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100352215; called by muse, mutect2
- DYNC2H1 | c.9194A>G p.E3065G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV100517648; called by muse, mutect2, varscan2
- GSDMA | c.1070A>G p.K357R | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.123); catalogued as rs1212418839, COSV52857101, COSV99227587; called by muse, mutect2
- HAUS2 | c.660T>C p.P220= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99535295; called by muse, mutect2
- PPP1R36 | c.1128G>A p.T376= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs772452565, COSV100072728; called by mutect2, varscan2
